Gene-level copy-number profile of tumor specimen TARGET-10-PARCVM-03A from TARGET case TARGET-10-PARCVM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,459 days).
Specimen TARGET-10-PARCVM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.576673ac-b16f-57b4-8bef-56ccc29cea67.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARCVM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate.
https://portal.gdc.cancer.gov/files/7a0ad97c-38da-45ab-8fa4-b68a31b7d46b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 3,126; copy number 2: 57,080; copy number 3: 25; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes: TRGV5P, TRGV5.
- chr7:142,749,468–142,786,224, 5 genes: PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,929,457–21,995,301, 3 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
